Gene-level copy-number profile of tumor specimen TCGA-2G-AAER-01A from TCGA case TCGA-2G-AAER, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 30.5 years (11,156 days).
Specimen TCGA-2G-AAER-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2ff0eab0-45b6-4f17-9899-017bea99953c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAER-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,746 have no estimate.
https://portal.gdc.cancer.gov/files/2f0ea1c6-3a7a-4a9f-b37b-ad29097f6e34

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 478; copy number 2: 6,980; copy number 3: 34,422; copy number 4: 10,460; copy number 5: 5,807; copy number 6: 701; copy number 7: 28.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 28 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:46,712,115–46,812,574, 2 genes, copy number 7 (within-gene range 3–7): AC109583.1, PRSS50.
- chr3:46,742,092–46,812,558, 5 genes, copy number 7: PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P.
- chr21:13,038,160–13,681,138, 21 genes, copy number 7: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1, AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3, GTF2IP2, VN1R8P, LINC01674, SNX19P1, OR4K11P, OR4K12P, POTED, RNU6-286P, MIR3118-1, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3.

Autosomal genes at a single copy (total copy number 1): 14. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
